Somatic mutation profile of tumor specimen TCGA-83-5908-01A (aliquot TCGA-83-5908-01A-21D-2284-08) from TCGA case TCGA-83-5908, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.6 years (21,760 days).
Specimen TCGA-83-5908-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8fd4269-c9e6-4f1d-be5f-eee80fc4b9fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-83-5908-10A (Blood Derived Normal), aliquot TCGA-83-5908-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ab6e0cc-73f2-481f-8c74-e89161f6c6ed

The open-access MAF lists 252 somatic variants for this specimen: 191 protein-altering or splice-affecting, 57 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 57, Nonsense Mutation 15, Frame Shift Del 6, Splice Site 6, RNA 2, Nonstop Mutation 1, Splice Region 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 13/28 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- OTC | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as rs72558416, CM961056, COSV50001314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2
- ADAMTS2 | c.2914C>A p.R972S | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867846785, COSV52368134; called by muse, mutect2, varscan2
- ADGRG4 | c.8782C>A p.Q2928K | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99055425, COSV99794288; called by muse, mutect2, varscan2
- AFDN | c.3722G>T p.R1241L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV100652425; called by muse, mutect2, varscan2
- AKAP4 | c.2247G>T p.Q749H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV62073548; called by muse, mutect2, varscan2
- ANGPTL4 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV100035005, COSV56844983; called by muse, mutect2, varscan2
- ANK1 | c.1446C>A p.H482Q | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV99223858; called by muse, mutect2, varscan2
- ANO4 | c.661G>T p.D221Y (on ENST00000392977 / NM_001286615.2; = p.D186Y on NM_178826.4) | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100151863; called by muse, mutect2, varscan2
- ASZ1 | c.682C>G p.H228D | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1429440064, COSV52914693, COSV99497734; called by muse, mutect2, varscan2
- ATP2C1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1420871601, COSV100146243; called by muse, mutect2
- ATP8A1 | c.1206G>T p.Q402H | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100044887; called by muse, mutect2, varscan2
- ATRX | c.4724G>T p.C1575F | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64879640; called by muse, mutect2, varscan2
- AVIL | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57680273, COSV99142157; called by muse, mutect2, varscan2
- BCORL1 | c.3784C>A p.P1262T | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.644); catalogued as COSV99498395; called by muse, mutect2, varscan2
- BICRA | c.1460C>G p.S487* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | catalogued as COSV67606537; called by muse, mutect2
- BLOC1S4 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100296599; called by muse, mutect2
- BNC2 | c.2612C>A p.A871E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101032087; called by muse, mutect2, varscan2
- CABS1 | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.471); catalogued as COSV99908940; called by muse, mutect2, varscan2
- CAPN12 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100184940; called by muse, mutect2, varscan2
- CBLL2 | c.1241C>A p.S414* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100081447; called by muse, mutect2, varscan2
- CD300E | c.498-2A>T p.X166_splice | Splice Site (SNP) | VAF 32/103 reads (31%) | catalogued as COSV100151153; called by muse, mutect2, varscan2
- CEACAM1 | c.1046C>G p.S349C | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.932); catalogued as COSV99362143; called by muse, mutect2, varscan2
- CGN | c.2833G>T p.G945W | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs770084960, COSV54974364, COSV99641864; called by muse, mutect2, varscan2
- CLDN18 | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.141); catalogued as COSV100648202, COSV59302131; called by muse, mutect2, varscan2
- CNDP2 | c.367G>T p.G123C | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs894133014, COSV100158885, COSV60839013; called by muse, mutect2, varscan2
- CPED1 | c.3004C>A p.H1002N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs147434701, COSV100119948; called by muse, mutect2, varscan2
- CSN3 | c.542C>G p.T181R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as COSV100515249, COSV59244055; called by muse, mutect2, varscan2
- CYTL1 | c.322A>T p.R108W | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100312352; called by muse, mutect2
- DGKB | c.1683G>T p.R561S | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99336291, COSV99337606; called by muse, mutect2, varscan2
- DHX40 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV52067742; called by muse, mutect2, varscan2
- DIDO1 | c.3772C>G p.P1258A | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99824646; called by muse, mutect2, varscan2
- DMBX1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.836); catalogued as rs1557789988, COSV100760656; called by muse, mutect2, varscan2
- DMD | c.811C>G p.Q271E | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV55851197, COSV55870491; called by muse, mutect2, varscan2
- DNASE1L1 | c.724A>T p.T242S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99185809; called by muse, mutect2, varscan2
- DOCK6 | c.5488G>A p.D1830N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV99624642; called by muse, mutect2, varscan2
- DTX1 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs868570524, COSV57502743; called by muse, mutect2
- EIF4ENIF1 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100348846; called by muse, mutect2
- EPHB4 | c.1169G>C p.W390S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.303); catalogued as COSV100639401; called by muse, mutect2, varscan2
- FILIP1 | c.1168A>G p.M390V | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99383799; called by muse, mutect2, varscan2
- FNDC8 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV99338631; called by muse, mutect2, varscan2
- FRMD6 | c.913G>A p.G305R (on ENST00000344768 / NM_001267046.2; = p.G297R on NM_152330.4) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100655547; called by muse, mutect2, varscan2
- FRMPD3 | c.3259C>A p.L1087M | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV99345615; called by muse, mutect2, varscan2
- GABRA4 | c.1526C>G p.P509R | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.837); catalogued as rs1052983845, COSV99973474; called by muse, mutect2, varscan2
- GALNT3 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.733); catalogued as CD101914, COSV101204878; called by muse, mutect2
- GALNT7 | c.195A>T p.R65S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV99396870; called by muse, mutect2, varscan2
- GAPVD1 | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99782614; called by muse, mutect2
- GLI2 | c.3275G>T p.R1092M (on ENST00000361492 / NM_001374353.1; = p.R1109M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV100082269; called by muse, mutect2, varscan2
- GLIPR1L2 | c.596C>G p.T199R | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV57553797, COSV57556358; called by muse, mutect2, varscan2
- GOT1L1 | c.260T>A p.L87H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100294313; called by muse, mutect2
- GPATCH11 | c.477G>A p.M159I (on ENST00000409774; = p.M137I on NM_174931.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.067); catalogued as rs1327285592, COSV99930821; called by muse, mutect2
- GPX5 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101297285, COSV69079458; called by muse, mutect2, varscan2
- GRIA4 | c.225C>G p.N75K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99228735; called by muse, mutect2, varscan2
- GRIN2B | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV101662907; called by muse, mutect2, varscan2
- GRM6 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV51433860, COSV99179441; called by muse, mutect2
- H3-4 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV100797341, COSV64211202; called by muse, mutect2
- HAVCR1 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.102); catalogued as COSV100207929; called by muse, mutect2, varscan2
- HEPHL1 | c.2372C>A p.T791K | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV59897254; called by muse, mutect2, varscan2
- HERC1 | c.8809G>A p.E2937K | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV101496306; called by muse, mutect2, varscan2
- HERC1 | c.6640G>A p.E2214K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101496307; called by muse, mutect2
- HHIPL2 | c.744del p.S249Vfs*15 | Frame Shift Del (DEL) | VAF 18/85 reads (21%) | catalogued as rs756804805; called by mutect2, pindel, varscan2
- HIPK1 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | catalogued as COSV65786363; called by muse, mutect2, varscan2
- HOXA2 | c.899C>A p.T300K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.962); catalogued as COSV99760993; called by muse, mutect2, varscan2
- HPX | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs370115077; called by muse, mutect2, varscan2
- HTT | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs764859997; called by muse, mutect2, varscan2
- IFNW1 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV101207600; called by muse, mutect2, varscan2
- IGSF10 | c.4084C>G p.P1362A | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1372461167, COSV99176602, COSV99196650; called by muse, mutect2
- IL17RE | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV99924675; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1075G>T p.G359W | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1187949897, COSV61158350; called by muse, mutect2, varscan2
- ISG20L2 | c.426G>C p.Q142H | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.205); catalogued as COSV57459451; called by muse, mutect2, varscan2
- IVL | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.073); catalogued as COSV100908099, COSV64216367; called by muse, mutect2, varscan2
- JPH2 | c.299C>G p.S100* | Nonsense Mutation (SNP) | VAF 32/95 reads (34%) | catalogued as COSV100652511; called by muse, mutect2, varscan2
- KCNH1 | c.865A>G p.M289V | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.506); catalogued as COSV55069956; called by muse, mutect2, varscan2
- KDM3A | c.3277C>T p.R1093W | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs979151200, COSV100459951; called by muse, mutect2
- KIF1A | c.2445G>T p.M815I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100239781; called by muse, mutect2
- KIR2DL1 | c.719A>T p.N240I | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99382642, COSV99383657; called by muse, mutect2, varscan2
- KRT36 | c.1289C>G p.S430C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100057317, COSV60203577; called by muse, mutect2, varscan2
- LAMP3 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV55617131; called by muse, mutect2, varscan2
- LGI3 | c.877T>C p.Y293H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1233908332, COSV100102820; called by muse, mutect2, varscan2
- LIMA1 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100372191, COSV57965646; called by muse, mutect2, varscan2
- LRP1B | c.4294G>A p.V1432M | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV101252175; called by muse, mutect2
- LRP8 | c.1774+2T>G p.X592_splice | Splice Site (SNP) | VAF 44/180 reads (24%) | catalogued as COSV100036038; called by muse, mutect2, varscan2
- LY9 | c.893C>A p.T298K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.141); catalogued as COSV54431964, COSV99626174; called by muse, mutect2, varscan2
- MED12 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as COSV100375970; called by muse, mutect2, varscan2
- MINDY2 | c.1308G>T p.Q436H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV100376247; called by muse, mutect2, varscan2
- MSH4 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as rs1334110962, COSV54202018, COSV99590584; called by muse, mutect2
- MXRA5 | c.8096G>A p.R2699H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs1304167780, COSV54256925; called by muse, mutect2, varscan2
- MYLK3 | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as COSV101189045; called by muse, mutect2, varscan2
- MYO7B | c.2742G>C p.M914I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV101267871; called by mutect2, varscan2
- NAALAD2 | c.81G>A p.V27= | Splice Region (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100428018; called by muse, mutect2, varscan2
- NCKAP5 | c.2968G>C p.E990Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV100489952; called by muse, mutect2
- NDST4 | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.61); catalogued as COSV99995377; called by muse, mutect2, varscan2
- NLRC5 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs774278359, COSV99346405; called by muse, mutect2
- NLRP9 | c.1424A>T p.Q475L | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100242547; called by muse, mutect2, varscan2
- NME8 | c.13A>T p.K5* | Nonsense Mutation (SNP) | VAF 32/152 reads (21%) | catalogued as COSV99552774; called by muse, mutect2, varscan2
- NOSIP | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 127/615 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV100182107; called by muse, mutect2, varscan2
- NPAS4 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.503); catalogued as COSV100214768; called by muse, mutect2, varscan2
- NR1H4 | c.147G>C p.Q49H (on ENST00000551379 / NM_001206993.2; = p.Q39H on NM_005123.4) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.615); catalogued as COSV51854263; called by muse, mutect2
- NRG1 | c.1718C>A p.S573* (on ENST00000405005 / NM_013964.5; = p.S578* on NM_013956.5) | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as COSV99827562; called by muse, mutect2, varscan2
- NRK | c.1879C>G p.L627V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99686532; called by muse, mutect2, varscan2
- NRSN1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs769474942, COSV65894204; called by muse, mutect2, varscan2
- NXPE3 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs746081450, COSV56288684, COSV99839742; called by muse, mutect2, varscan2
- OPCML | c.513C>G p.H171Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV100097771; called by muse, mutect2, varscan2
- OPHN1 | c.1362-2A>C p.X454_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100830203; called by muse, mutect2, varscan2
- OPTN | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779662670, COSV99537224; called by muse, mutect2, varscan2
- OR2G6 | c.200C>A p.S67* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as rs560459259, COSV100598091, COSV58573816; called by muse, mutect2, varscan2
- OR2M7 | c.674T>G p.V225G | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100522411; called by muse, mutect2, varscan2
- P4HA1 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as COSV99696538; called by muse, mutect2
- PAPPA2 | c.93G>C p.K31N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); catalogued as COSV62776206, COSV62782333; called by muse, mutect2, varscan2
- PCDHB16 | c.168G>T p.L56F | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV99501015; called by muse, mutect2, varscan2
- PCDHGA2 | c.1993G>T p.A665S | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV99530230; called by muse, mutect2, varscan2
- PCSK6 | c.1235G>T p.C412F | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100082978; called by muse, mutect2, varscan2
- PHLDB2 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.743); catalogued as rs375225872; called by muse, mutect2, varscan2
- PKD1 | c.5804G>T p.R1935L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.239); catalogued as rs770331568, COSV99237103; called by muse, mutect2, varscan2
- PLEKHG5 | c.3131G>C p.*1044Sext*10 (on ENST00000400915 / NM_001042663.3; = p.*1007Sext*10 on NM_020631.6) | Nonstop Mutation (SNP) | VAF 33/135 reads (24%) | catalogued as COSV100556018; called by muse, mutect2, varscan2
- PLXNB2 | c.4750G>T p.E1584* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100833845; called by muse, mutect2, varscan2
- PLXNB3 | c.1572C>A p.H524Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100737036, COSV100737083; called by muse, mutect2, varscan2
- PLXNB3 | c.4751G>T p.G1584V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737086; called by muse, mutect2, varscan2
- PNPLA7 | c.3079G>C p.E1027Q | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV53008224, COSV99480022; called by muse, varscan2
- POC5 | c.1211C>G p.S404* (on ENST00000428202 / NM_001099271.2; = p.S379* on NM_152408.2) | Nonsense Mutation (SNP) | VAF 15/106 reads (14%) | catalogued as COSV100994250; called by muse, mutect2, varscan2
- PRG4 | c.2749G>C p.D917H | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV100798094; called by muse, mutect2, varscan2
- PRL | c.359A>T p.N120I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV100122931; called by muse, mutect2, varscan2
- PRSS36 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV99191227; called by muse, mutect2, varscan2
- PRSS58 | c.417C>A p.S139R | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV101616082; called by muse, mutect2, varscan2
- PSME1 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as COSV99246005; called by muse, mutect2, varscan2
- PTPN20 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438877736; called by muse, mutect2, varscan2
- PTPRA | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs753066418, COSV99399106; called by muse, mutect2, varscan2
- RAD51AP1 | c.953G>T p.S318I (on ENST00000228843 / NM_001130862.2; = p.S301I on NM_006479.5) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV99961045; called by muse, mutect2
- RENBP | c.557C>A p.A186E | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.209); catalogued as COSV100128373; called by muse, mutect2, varscan2
- RNF10 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs111483466, COSV100378454; called by muse, mutect2, varscan2
- RP1L1 | c.3547G>C p.D1183H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV101222929; called by muse, mutect2, varscan2
- RPGRIP1 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV99250384; called by muse, mutect2, varscan2
- RRM2B | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as COSV99309860; called by muse, mutect2
- SASH3 | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV100795154; called by muse, mutect2, varscan2
- SBSN | c.1626C>A p.N542K (on ENST00000452271 / NM_001166034.2; = p.N199K on NM_198538.4) | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as rs745475473, COSV101510033; called by muse, mutect2, varscan2
- SCAMP4 | c.96G>C p.E32D | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV100280140; called by muse, mutect2, varscan2
- SLC17A8 | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100035162; called by muse, mutect2, varscan2
- SLC17A8 | c.1425+1G>A p.X475_splice | Splice Site (SNP) | VAF 12/119 reads (10%) | catalogued as COSV100035165; called by muse, mutect2, varscan2
- SLC41A1 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900325; called by muse, mutect2, varscan2
- SLC6A14 | c.1274T>C p.F425S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100903062; called by muse, mutect2, varscan2
- SLC6A19 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs202242697, COSV100443212; called by muse, mutect2, varscan2
- SLC6A5 | c.2132C>G p.P711R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100116395, COSV100116585; called by muse, varscan2
- SLFNL1 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.135); catalogued as COSV100262772; called by muse, mutect2
- SNX5 | c.718G>T p.V240F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs775946902, COSV100898967; called by muse, mutect2, varscan2
- SOGA1 | c.1481G>T p.R494L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs917966817, COSV52916727, COSV99412702; called by muse, mutect2, varscan2
- SUGP2 | c.2051G>T p.R684L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100431427, COSV58260177, COSV58264968; called by muse, mutect2
- SYNDIG1L | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV59048141; called by muse, mutect2, varscan2
- SYNE1 | c.25384G>A p.E8462K (on ENST00000367255 / NM_182961.4; = p.E8414K on NM_033071.3) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs767021373, COSV99552547; called by muse, mutect2, varscan2
- SYNGR1 | c.292G>T p.V98F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99335472; called by muse, mutect2, varscan2
- TAF1L | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99644075; called by muse, mutect2, varscan2
- TAF7L | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV100229301; called by muse, mutect2, varscan2
- TAS2R4 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.935); catalogued as COSV99924617; called by muse, mutect2
- TAT | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778438405, COSV63532496; called by muse, mutect2, varscan2
- TEDC1 | c.1425G>T p.Q475H (on ENST00000392523 / NM_001367178.1; = p.Q406H on NM_001134875.1) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV100321968; called by muse, mutect2, varscan2
- TGFBR3 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.085); catalogued as COSV99282370; called by muse, mutect2, varscan2
- THRB | c.785G>C p.G262A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.133); catalogued as COSV99769226; called by muse, mutect2, varscan2
- TIMD4 | c.56T>A p.L19Q | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99192485; called by muse, mutect2, varscan2
- TLN2 | c.3687+1G>T p.X1229_splice | Splice Site (SNP) | VAF 12/120 reads (10%) | catalogued as COSV100167937; called by muse, mutect2
- TLR4 | c.2227C>A p.Q743K (on ENST00000355622 / NM_138554.5; = p.Q703K on NM_003266.4) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV100842642; called by muse, mutect2, varscan2
- TLR5 | c.218A>T p.Q73L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV100643158; called by muse, mutect2, varscan2
- TMEFF1 | c.398A>T p.K133I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV100614378; called by muse, mutect2, varscan2
- TMEM132B | c.1616C>A p.A539D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as COSV100168466; called by muse, mutect2, varscan2
- TMEM47 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV99327462; called by muse, mutect2, varscan2
- TNFRSF10B | c.35C>A p.S12* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99375134; called by muse, varscan2
- TNXB | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100925783; called by muse, mutect2, varscan2
- TTN | c.53410G>C p.E17804Q (on ENST00000591111; = p.E10380Q on NM_003319.4) | Missense Mutation (SNP) | VAF 16/118 reads (14%) | PolyPhen benign (0.099); catalogued as COSV100593351; called by muse, mutect2, varscan2
- USP45 | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100328046; called by muse, mutect2, varscan2
- VCAN | c.67A>T p.K23* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99424573; called by muse, mutect2
- WDR70 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 12/91 reads (13%) | catalogued as COSV99457483; called by muse, mutect2, varscan2
- XKR9 | c.897G>T p.L299F | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV101281817; called by muse, mutect2, varscan2
- ZFR | c.2328G>T p.K776N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV99415315; called by muse, mutect2, varscan2
- ZMIZ2 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99536547; called by muse, mutect2, varscan2
- ZMYND8 | c.257G>C p.R86P (on ENST00000311275 / NM_001363741.2; = p.R106P on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99519491; called by muse, mutect2, varscan2
- ZNF142 | c.4813G>A p.E1605K (on ENST00000411696 / NM_001379660.1; = p.E1405K on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV101376896; called by muse, mutect2, varscan2
- ZNF208 | c.3116G>T p.S1039I | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.24); catalogued as COSV101236787; called by muse, mutect2, varscan2
- ZNF236 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1568210064, COSV99468942; called by muse, mutect2, varscan2
- ZNF470 | c.1600G>T p.E534* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100401069; called by muse, mutect2, varscan2
- ZNF606 | c.2341C>G p.Q781E | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.482); catalogued as COSV100071634, COSV58705135; called by muse, mutect2
- ZNF831 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64039668, COSV64044977; called by muse, mutect2, varscan2
- ZNF91 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56091761; called by muse, mutect2, varscan2
- ZNF91 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs775588959, COSV100322133; called by muse, mutect2, varscan2
- APOA4 | c.562del p.A188Pfs*54 | Frame Shift Del (DEL) | VAF 34/217 reads (16%) | called by mutect2, pindel, varscan2
- ATG2B | c.5579+1del p.X1860_splice | Splice Site (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- CTDSPL | c.604G>A p.G202R (on ENST00000273179 / NM_001008392.2; = p.G191R on NM_005808.3) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HP1BP3 | c.1259del p.G420Efs*53 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- MLLT6 | c.2894C>G p.T965S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PPP1R13B | c.1680del p.S562Qfs*13 | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | called by mutect2, pindel, varscan2
- SLC30A1 | c.184_185delinsT p.R62Cfs*18 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by pindel, varscan2*
- XIRP2 | c.887del p.Q296Rfs*28 (on ENST00000628543; = p.Q471Rfs*28 on NM_152381.6) | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, varscan2
- XIRP2 | c.888G>T p.Q296H (on ENST00000628543; = p.Q471H on NM_152381.6) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- ADGRG7 | c.102C>A p.I34= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV56301966, COSV99840490; called by muse, mutect2, varscan2
- ALOX5 | c.1209C>T p.F403= | Silent (SNP) | VAF 17/151 reads (11%) | catalogued as rs148091491; called by muse, mutect2, varscan2
- BAZ2A | c.4956G>C p.R1652= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV99464691; called by muse, mutect2, varscan2
- CALB1 | c.129C>A p.L43= | Silent (SNP) | VAF 50/148 reads (34%) | catalogued as COSV99617912; called by muse, mutect2, varscan2
- CCDC88C | c.966G>A p.A322= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs1374468727, COSV66235985; called by muse, mutect2, varscan2
- CSF1 | c.1347G>C p.R449= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as COSV100294286; called by muse, mutect2, varscan2
- CYB561D1 | c.613C>T p.L205= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as rs1461764886, COSV100149740; called by muse, mutect2, varscan2
- DCAF12L2 | c.1032G>T p.L344= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV100758444; called by muse, mutect2, varscan2
- EFHB | c.312G>C p.L104= | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as COSV99859084; called by muse, mutect2
- FAR2 | c.1431C>A p.I477= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as COSV51724389, COSV99478711; called by muse, mutect2, varscan2
- FERD3L | c.345C>T p.F115= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99284674; called by muse, mutect2, varscan2
- FLNA | c.441C>T p.H147= | Silent (SNP) | VAF 43/259 reads (17%) | catalogued as rs781951563, COSV100774261; ClinVar: likely benign; called by muse, mutect2, varscan2
- GABRE | c.826C>A p.R276= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as rs774077841, COSV100944206, COSV64820670; called by muse, mutect2, varscan2
- GABRE | c.726C>G p.L242= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV100944207, COSV64821431; called by muse, mutect2, varscan2
- GJB4 | c.456C>A p.L152= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100258251; called by muse, mutect2, varscan2
- GOLGA2 | c.750G>A p.R250= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV101425783; called by muse, mutect2, varscan2
- GPER1 | c.540C>G p.L180= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV99866727; called by muse, mutect2, varscan2
- GRIN3A | c.2455A>C p.R819= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs376371207; called by muse, mutect2, varscan2
- HBZ | c.57C>A p.S19= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99429378; called by muse, mutect2, varscan2
- HCFC1 | c.2670C>G p.V890= | Silent (SNP) | VAF 12/143 reads (8%) | catalogued as COSV100128375; called by muse, mutect2
- HDLBP | c.2286C>T p.I762= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV100189839; called by muse, mutect2, varscan2
- HOXD12 | c.630G>C p.T210= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV101184123, COSV66832350; called by muse, mutect2, varscan2
- IQCA1 | c.279G>T p.L93= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99608539; called by muse, varscan2
- IQCE | c.498G>C p.L166= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as COSV100383172, COSV58077115; called by muse, mutect2
- IZUMO1R | c.594G>T p.R198= (on ENST00000440961; = p.R205= on NM_001199206.3) | Silent (SNP) | VAF 34/176 reads (19%) | catalogued as COSV100126794; called by muse, mutect2, varscan2
- KIAA1549 | c.1887A>T p.T629= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99649750; called by muse, mutect2
- KIT | c.550C>T p.L184= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99853179; called by muse, mutect2, varscan2
- KRTAP9-2 | c.369C>A p.P123= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as COSV66646992; called by muse, mutect2
- MAMLD1 | c.2112G>T p.P704= | Silent (SNP) | VAF 56/228 reads (25%) | catalogued as COSV99475507; called by muse, mutect2, varscan2
- MATN2 | c.2845C>T p.L949= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99645637; called by muse, mutect2
- MED12 | c.639G>T p.G213= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as COSV100375972; called by muse, mutect2, varscan2
- MEPE | c.495G>A p.G165= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV100734842, COSV63074013; called by muse, mutect2, varscan2
- OR1N2 | c.228C>T p.F76= | Silent (SNP) | VAF 20/197 reads (10%) | catalogued as rs1190495473, COSV65461183; called by muse, mutect2
- OTULINL | c.990C>T p.Y330= | Silent (SNP) | VAF 7/135 reads (5%) | catalogued as rs1361360804, COSV99947017; called by muse, mutect2
- PCDHB15 | c.1419C>G p.V473= | Silent (SNP) | VAF 23/212 reads (11%) | catalogued as COSV99178815; called by muse, mutect2, varscan2
- PLEKHO2 | c.963G>A p.L321= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV100060562; called by muse, mutect2, varscan2
- PREX2 | c.792G>A p.V264= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1393403296, COSV55771335, COSV99904875; called by muse, mutect2, varscan2
- PRRC2B | c.483A>C p.S161= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100621392; called by muse, mutect2
- PRSS1 | c.333C>T p.I111= | Silent (SNP) | VAF 44/197 reads (22%) | catalogued as COSV100297693; called by muse, varscan2
- PSG9 | c.1239C>G p.V413= | Silent (SNP) | VAF 58/290 reads (20%) | catalogued as COSV99392032; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1143C>G p.L381= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV99769666; called by muse, mutect2, varscan2
- RADIL | c.1110G>A p.A370= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1388430431, COSV101271244; called by muse, mutect2
- RNASE2 | c.90A>G p.P30= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV100482015; called by muse, mutect2, varscan2
- ROBO2 | c.1581A>G p.K527= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100164077; called by muse, mutect2
- RUSC1 | c.2346C>G p.L782= (on ENST00000368352 / NM_001105203.2; = p.L313= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as COSV52742835, COSV99429423; called by muse, mutect2, varscan2
- SALL4 | c.1695C>T p.P565= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV99409144; called by muse, mutect2, varscan2
- SCGN | c.582T>C p.S194= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV100618646; called by muse, varscan2
- SCN2A | c.5517C>G p.L1839= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV99330033; called by muse, mutect2, varscan2
- SNAP47 | c.1191G>T p.L397= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100247907; called by muse, mutect2, varscan2
- SYNPO2L | c.2673C>T p.S891= (on ENST00000394810 / NM_001114133.3; = p.S667= on NM_024875.5) | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV65736991; called by muse, mutect2, varscan2
- TRMT12 | c.757C>T p.L253= | Silent (SNP) | VAF 16/258 reads (6%) | catalogued as COSV100149074; called by muse, mutect2
- TRPC6 | c.1690T>C p.L564= | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as COSV100723452; called by muse, mutect2
- TTN | c.40839C>A p.I13613= (on ENST00000591111; = p.I6189= on NM_003319.4) | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100593354; called by muse, mutect2
- UNC79 | c.5010C>G p.V1670= (on ENST00000393151 / NM_001346218.2; = p.V1493= on NM_020818.5) | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV99825680; called by muse, mutect2
- WDR6 | c.3365G>A p.*1122= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100556145, COSV100556451; called by muse, mutect2, varscan2
- ZFHX4 | c.7656G>T p.L2552= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV50695654, COSV99255736; called by muse, mutect2, varscan2
- ZIC1 | c.540G>A p.Q180= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV99291486; called by mutect2, varscan2
- AL353804.7 | chrX:73846402 G>A | 5'Flank (SNP) | VAF 13/60 reads (22%) | catalogued as rs372838115; called by muse, mutect2, varscan2
- MIR523 | n.24G>A | RNA (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- OFCC1 | n.434G>C | RNA (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- TMEM187 | c.-2A>T | 5'UTR (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100890131; called by muse, mutect2, varscan2
